Surgical pathology report (de-identified scan), TCGA case TCGA-4V-A9QQ, project TCGA-THYM (Thymoma), tissue source site Hospital Louis Pradel, specimen TCGA-4V-A9QQ-01A (Primary Tumor).

[page 1 of 2]
MICROSCOPIC EXAMINATION

1 mediastinal tumor

This is the place of a lymphoepithelial proliferation with limited amount of lymphocytes and atypic epithelial cells. Resection is complete. No Hassall corpuscle are seen.

2 lower left parietal pleura :

Samples (block 2) of this nodule

show tumor infiltration with epithelial cell contingent

large round or polygonal in an abundant lymphoid stroma.

A remote sampling (block 3) shows no lymphangitis .

ICD O-3
Thymoma, type B3,
malignant 8585/3
Site ^{site} Thymus C37.9
^{path} Mediastinum C38.3
p 4/2/14

3 Trimming (pleura next to the descending thoracic aorta)

The fragment of 25 mm as is included (block 4) is constituted by a fibro - fatty tissue and muscle . No tumor infiltration.

4 upper left parietal pleura :

The fragment comprises a 20 cm 15 mm corresponding nodule (blocks 5 and 6) at the same aspect of epithelial thymoma with a contingent closely entangled in this lymphoid tissue with a nodule that infiltrated focally striated muscle.

5 ° overlaps depth of the upper parietal pleura included such (block 8) without tumor infiltration.

CONCLUSION :

B3 thymoma

Stage IVA

No invasion of the lymph nodes

[page 2 of 2]
Dr.

Source: NCI Genomic Data Commons file d5d6dd2f-2340-4a1b-8f12-8031013331c2 (TCGA-4V-A9QQ.FA7EAFFE-8B79-412E-927B-A08E07E08B88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).